Gene-level copy-number profile of tumor specimen TCGA-R6-A8W8-01B from TCGA case TCGA-R6-A8W8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 72.6 years (26,535 days).
Specimen TCGA-R6-A8W8-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d172ac9d-b3b6-441e-a9c1-e038707e1eb8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A8W8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53d86b26-e03c-4e29-b66a-73b749449a28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,271; copy number 2: 28,620; copy number 3: 21,257; copy number 4: 5,423; copy number 5: 1,063; copy number 6: 687; copy number 7: 1,029; copy number 8: 136; copy number 10: 3; copy number 11: 79; copy number 12: 1; copy number 14: 58; copy number 16: 9; copy number 17: 15; copy number 20: 22; copy number 26: 51; copy number 31: 2; copy number 34: 46; copy number 44: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A8W8-01B-11D-A37B-01): tumor purity 0.72, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,856,389–60,856,605, 1 gene: U3.
- chr16:78,495,926–78,535,648, 3 genes: AC046158.1, AC046158.4, AC046158.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,226 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:5,187,172–5,256,761, 5 genes, copy number 5: AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1.
- chr4:115,628,812–116,599,611, 12 genes, copy number 6: RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1.
- chr4:143,336,762–143,474,568, 1 gene, copy number 7 (within-gene range 4–7): GAB1.
- chr4:143,424,753–152,116,497, 134 genes, copy number 7–10 (broad region; genes not listed).
- chr6:167,607–1,324,022, 24 genes, copy number 6: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394.
- chr6:31,897,785–32,647,062, 50 genes, copy number 7 (within-gene range 4–7): C2, AL645922.1, C2-AS1, CFB, NELFE, MIR1236, SKIV2L, DXO, STK19, C4A, C4A-AS1, CYP21A1P, TNXA, STK19B, C4B, C4B-AS1, CYP21A2, TNXB, RNA5SP206, AL662884.2, AL662884.5, ATF6B, FKBPL, PRRT1, AL662884.4, AL662884.3, PPT2, PPT2-EGFL8, EGFL8, AGPAT1, MIR6721, RNF5, MIR6833, AGER, AL662884.1, PBX2, GPSM3, NOTCH4, TSBP1-AS1, TSBP1, HNRNPA1P2, RNU6-603P, BTNL2, HLA-DRA, HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1.
- chr6:38,675,925–47,309,905, 213 genes, copy number 5–17 (within-gene range 2–17) (broad region; genes not listed).
- chr6:47,656,436–48,214,794, 11 genes, copy number 5: ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr6:54,485,169–54,945,099, 8 genes, copy number 6: CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1.
- chr6:63,275,951–65,789,287, 21 genes, copy number 6: LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1.
- chr7:46,634,614–108,456,717, 1,190 genes, copy number 5–44 (within-gene range 2–44) (broad region; genes not listed).
- chr7:158,532,718–159,233,377, 14 genes, copy number 5: MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:97,132,835–145,066,685, 766 genes, copy number 5–6 (broad region; genes not listed).
- chr10:120,069,980–120,600,124, 5 genes, copy number 5: AL355298.1, RPL21P16, AC073587.1, PLPP4, LINC01561.
- chr14:53,685,139–53,991,995, 6 genes, copy number 5 (within-gene range 4–5): LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1.
- chr14:73,040,619–78,060,278, 176 genes, copy number 5–7 (broad region; genes not listed).
- chr14:78,177,803–78,283,376, 3 genes, copy number 7: RNA5SP388, RPS26P48, AF099810.1.
- chr15:42,491,233–45,931,069, 137 genes, copy number 5 (broad region; genes not listed).
- chr16:5,078,168–5,235,822, 7 genes, copy number 6: AC026458.1, EEF2KMT, AC026458.2, AC074051.3, ENPP7P14, AC074051.1, LINC02164.
- chr16:5,260,686–5,289,409, 3 genes, copy number 6: AC074051.2, RPS3AP48, SNRPCP20.
- chr18:11,609,596–12,776,140, 56 genes, copy number 5: SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA.
- chr18:20,946,906–21,704,780, 15 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1.
- chr18:21,711,950–21,724,229, 2 genes, copy number 5: AC106037.1, Y_RNA.
- chr18:71,890,409–71,944,577, 2 genes, copy number 5: AC069114.1, AC069114.2.
- chr19:18,957,957–27,984,984, 257 genes, copy number 5 (broad region; genes not listed).
- chr20:33,316,869–36,088,192, 108 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 423. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
